Somatic mutation profile of tumor specimen 0DU81F from CCDI case PBCKSL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.0 years (4,753 days).
Specimen 0DU81F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e4a1e34-c788-4c75-bd08-07bc291b9abd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU80B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4435a58a-cd94-4906-9264-9463b4be3eae

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERAS | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 50/477 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs913149474; called by muse, mutect2, varscan2
- ARX | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 111/757 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- LOXHD1 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 79/1010 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR51E2 | c.434T>G p.I145S | Missense Mutation (SNP) | VAF 109/887 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- OR5D14 | c.547T>C p.Y183H | Missense Mutation (SNP) | VAF 56/421 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- VPS13A | c.7545G>C p.E2515D | Missense Mutation (SNP) | VAF 26/762 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); called by muse, mutect2
- HERC1 | c.6999G>A p.T2333= | Silent (SNP) | VAF 30/1084 reads (3%) | catalogued as rs1162444461; called by muse, mutect2
- ARMCX4 | c.1038+3272G>A | Intron (SNP) | VAF 120/967 reads (12%) | called by muse, mutect2, varscan2
- KRT25 | c.-16C>T | 5'UTR (SNP) | VAF 20/287 reads (7%) | called by muse, mutect2
